Somatic mutation profile of tumor specimen MMRF_2833_1_BM_CD138pos (aliquot MMRF_2833_1_BM_CD138pos_T1_KHS5U_L16563) from MMRF case MMRF_2833, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 52.2 years (19,056 days).
Specimen MMRF_2833_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 83198263-edd7-4474-9449-48440a34b517.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2833_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2833_1_PB_WBC_C2_KHS5U_L16610; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bddffdc3-41cb-4517-967f-c76ca7e35da0

The open-access MAF lists 110 somatic variants for this specimen: 45 protein-altering or splice-affecting, 15 silent, 50 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, 3'UTR 27, Silent 15, Intron 12, 5'UTR 5, Nonsense Mutation 4, 5'Flank 4, Splice Region 2, 3'Flank 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHD2 | c.5035C>T p.R1679* | Nonsense Mutation (SNP) | VAF 40/185 reads (22%) | catalogued as rs797044912, CM162086, COSV101245952; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AP1M2 | c.1021G>A p.V341M | Missense Mutation (SNP) | VAF 50/206 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.305); catalogued as rs1456019889; called by muse, mutect2, varscan2
- ATM | c.7322T>A p.V2441D | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); catalogued as COSV53730768, COSV53755216; called by muse, mutect2, varscan2
- CPE | c.922A>G p.S308G | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT tolerated (0.6); PolyPhen benign (0.009); catalogued as COSV68581709; called by muse, mutect2, varscan2
- CYP4F2 | c.1276G>A p.G426R | Missense Mutation (SNP) | VAF 49/212 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs751427624, COSV99686261; called by muse, mutect2, varscan2
- FAT2 | c.9610G>A p.V3204I | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.213); catalogued as rs140898888; called by muse, mutect2, varscan2
- IMMP2L | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 30/412 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs748538581, COSV59223410; called by muse, mutect2
- ITGB5 | c.1813C>T p.R605C | Missense Mutation (SNP) | VAF 48/104 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs1467398756, COSV56153596; called by muse, mutect2, varscan2
- OR10G7 | c.173A>G p.Y58C | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1446738508; called by muse, mutect2, varscan2
- PXDN | c.3254A>G p.D1085G | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); catalogued as rs768212535; called by muse, mutect2, varscan2
- ROBO2 | c.74G>A p.R25H | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100164099, COSV59949799; called by muse, mutect2, varscan2
- SHROOM3 | c.5698C>T p.R1900C | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770837589, COSV56032949; called by muse, mutect2, varscan2
- STAC | c.1111-1G>T p.X371_splice | Splice Site (SNP) | VAF 63/220 reads (29%) | catalogued as COSV56215764; called by muse, mutect2, varscan2
- SYT1 | c.164C>A p.P55Q | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV54031080, COSV99039021; called by muse, mutect2, varscan2
- TREX2 | c.661C>T p.R221C (on ENST00000334497; = p.R178C on NM_080701.3) | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.956); catalogued as rs372809468; called by muse, mutect2, varscan2
- TRIL | c.2142G>C p.L714F | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.388); catalogued as COSV59867467; called by muse, mutect2, varscan2
- TTLL4 | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 57/195 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.018); catalogued as rs758811791, COSV51436432; called by muse, mutect2, varscan2
- TTN | c.101797G>C p.E33933Q (on ENST00000591111; = p.E26509Q on NM_003319.4) | Missense Mutation (SNP) | VAF 46/162 reads (28%) | PolyPhen benign (0.003); catalogued as COSV60129503; called by muse, mutect2, varscan2
- UHRF1BP1L | c.2146A>G p.I716V | Missense Mutation (SNP) | VAF 66/196 reads (34%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs368497727; called by muse, mutect2, varscan2
- USP29 | c.1973C>T p.S658F | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.287); catalogued as COSV54143923; called by muse, mutect2, varscan2
- ZNF793 | c.274C>T p.R92W | Missense Mutation (SNP) | VAF 38/175 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs200537636; called by muse, mutect2, varscan2
- BHLHE40 | c.81-7C>T | Splice Region (SNP) | VAF 74/191 reads (39%) | called by muse, mutect2, varscan2
- BTK | c.1770T>G p.I590M | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- CPXM2 | c.270G>T p.K90N | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- DOCK1 | c.1726G>A p.E576K | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.47); called by muse, mutect2, varscan2
- FCHO2 | c.4G>C p.V2L | Missense Mutation (SNP) | VAF 53/197 reads (27%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- GRIA3 | c.929C>A p.T310K | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- HTATSF1 | c.373T>A p.F125I | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HTR3A | c.26T>C p.L9P | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IGHV1-69D | c.234C>G p.N78K | Missense Mutation (SNP) | VAF 82/220 reads (37%) | SIFT tolerated (0.66); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IGLV5-45 | c.349A>C p.I117L | Missense Mutation (SNP) | VAF 82/329 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.062); called by muse, varscan2
- INTS6L | c.278G>T p.R93I | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2
- LYPD3 | c.952C>G p.P318A | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MACROH2A2 | c.746G>A p.R249H | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- MANSC4 | c.527C>A p.S176* | Nonsense Mutation (SNP) | VAF 35/119 reads (29%) | called by muse, mutect2, varscan2
- NCAM2 | c.1561T>C p.S521P | Missense Mutation (SNP) | VAF 43/131 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- POLR2B | c.3236C>T p.S1079F | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- PTGES2 | c.887+8T>C | Splice Region (SNP) | VAF 28/115 reads (24%) | called by mutect2, varscan2
- PYROXD2 | c.832G>A p.G278R | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.486); called by muse, mutect2, varscan2
- SGIP1 | c.2313G>T p.L771F | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TNPO2 | c.1451A>G p.K484R | Missense Mutation (SNP) | VAF 60/245 reads (24%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTC39B | c.1277G>A p.W426* | Nonsense Mutation (SNP) | VAF 23/102 reads (23%) | called by muse, varscan2
- WNK4 | c.1052A>C p.K351T | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- XG | c.239C>T p.S80F | Missense Mutation (SNP) | VAF 46/145 reads (32%) | SIFT tolerated (0.68); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- ZNF853 | c.1201C>T p.Q401* | Nonsense Mutation (SNP) | VAF 15/34 reads (44%) | called by muse, mutect2, varscan2
- ADGRF4 | c.1116C>T p.N372= | Silent (SNP) | VAF 40/142 reads (28%) | catalogued as rs777397219; called by muse, mutect2, varscan2
- CAT | c.465C>T p.I155= | Silent (SNP) | VAF 43/119 reads (36%) | catalogued as COSV99573476; called by muse, mutect2, varscan2
- COL6A3 | c.2529C>T p.D843= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as rs556079869, COSV55093894; ClinVar: conflicting interpretations of pathogenicity / likely benign; called by muse, mutect2, varscan2
- FAM47B | c.438A>T p.L146= | Silent (SNP) | VAF 31/110 reads (28%) | called by muse, mutect2, varscan2
- FAM9A | c.657A>C p.V219= | Silent (SNP) | VAF 14/30 reads (47%) | called by muse, mutect2, varscan2
- IGLV5-45 | c.231G>A p.K77= | Silent (SNP) | VAF 22/92 reads (24%) | catalogued as rs370576104; called by muse, varscan2
- LHX6 | c.1089C>T p.Y363= (on ENST00000373755 / NM_001242334.2; = p.Y392= on NM_014368.5) | Silent (SNP) | VAF 18/109 reads (17%) | called by muse, mutect2, varscan2
- MBD5 | c.2764C>T p.L922= | Silent (SNP) | VAF 48/174 reads (28%) | called by muse, mutect2, varscan2
- MXRA5 | c.921C>T p.I307= | Silent (SNP) | VAF 24/95 reads (25%) | called by muse, mutect2, varscan2
- PANX2 | c.747C>T p.Y249= | Silent (SNP) | VAF 53/191 reads (28%) | catalogued as rs763233719; called by muse, mutect2, varscan2
- PTPRE | c.1713C>T p.V571= | Silent (SNP) | VAF 68/203 reads (33%) | catalogued as rs952144784; called by muse, mutect2, varscan2
- SLITRK2 | c.681C>G p.L227= | Silent (SNP) | VAF 72/191 reads (38%) | catalogued as COSV59427636; called by muse, mutect2, varscan2
- TPGS1 | c.765G>A p.A255= | Silent (SNP) | VAF 21/78 reads (27%) | catalogued as rs927720581; called by muse, mutect2, varscan2
- WRNIP1 | c.1626T>C p.F542= | Silent (SNP) | VAF 36/75 reads (48%) | called by muse, mutect2, varscan2
- ZFP3 | c.1422G>A p.E474= | Silent (SNP) | VAF 54/188 reads (29%) | called by muse, mutect2, varscan2
- ASB15 | c.*483C>A | 3'UTR (SNP) | VAF 23/220 reads (10%) | called by muse, mutect2, varscan2
- BEND3 | c.*187G>A | 3'UTR (SNP) | VAF 49/198 reads (25%) | called by muse, mutect2, varscan2
- BOLL | c.*392_*395del | 3'UTR (DEL) | VAF 10/44 reads (23%) | catalogued as rs1313344648; called by pindel, varscan2
- C6orf132 | c.*2542G>A | 3'UTR (SNP) | VAF 53/173 reads (31%) | catalogued as rs1313966954; called by muse, mutect2, varscan2
- CDK19 | c.*4079A>G | 3'UTR (SNP) | VAF 7/38 reads (18%) | called by muse, mutect2, varscan2
- CDKN2A | chr9:21967713 A>T | 3'Flank (SNP) | VAF 5/53 reads (9%) | called by muse, mutect2
- CDX4 | c.*76T>C | 3'UTR (SNP) | VAF 11/28 reads (39%) | called by muse, mutect2, varscan2
- CEP164 | c.4096+79C>T | Intron (SNP) | VAF 21/113 reads (19%) | catalogued as rs1280491202; called by muse, mutect2, varscan2
- CHRNA4 | c.*935C>A | 3'UTR (SNP) | VAF 90/212 reads (42%) | called by muse, mutect2, varscan2
- COL4A1 | c.615+86A>C | Intron (SNP) | VAF 34/61 reads (56%) | called by muse, mutect2, varscan2
- CPA4 | c.*873A>T | 3'UTR (SNP) | VAF 21/88 reads (24%) | called by muse, mutect2, varscan2
- CYTH1 | c.*997G>T | 3'UTR (SNP) | VAF 53/103 reads (51%) | called by muse, mutect2, varscan2
- DBN1 | c.1879+38C>T | Intron (SNP) | VAF 33/131 reads (25%) | catalogued as rs1368719597; called by muse, mutect2, varscan2
- DMPK | c.676-47_676-36del | Intron (DEL) | VAF 6/32 reads (19%) | called by mutect2, pindel
- FAIM2 | c.*3528C>A | 3'UTR (SNP) | VAF 6/97 reads (6%) | called by muse, mutect2
- GRHL2 | c.*2282G>C | 3'UTR (SNP) | VAF 112/211 reads (53%) | called by muse, mutect2, varscan2
- GRIN3A | c.*1099C>A | 3'UTR (SNP) | VAF 6/88 reads (7%) | called by muse, mutect2
- HDAC8 | c.738-10881C>A | Intron (SNP) | VAF 4/19 reads (21%) | called by muse, mutect2, varscan2
- HSFX1 | chrX:149769739 C>T | 5'Flank (SNP) | VAF 22/71 reads (31%) | called by muse, mutect2, varscan2
- HYOU1 | c.2253+51G>C | Intron (SNP) | VAF 26/111 reads (23%) | called by muse, mutect2
- IGLV1-44 | c.-78A>C | 5'UTR (SNP) | VAF 16/54 reads (30%) | called by muse, mutect2
- IRS2 | c.-462G>C | 5'UTR (SNP) | VAF 3/36 reads (8%) | called by muse, mutect2
- KLF13 | c.*5335del | 3'UTR (DEL) | VAF 44/84 reads (52%) | called by mutect2, varscan2
- LRRC14 | c.*360C>G | 3'UTR (SNP) | VAF 101/192 reads (53%) | called by muse, mutect2, varscan2
- MALT1 | c.*5391C>T | 3'UTR (SNP) | VAF 3/17 reads (18%) | called by muse, mutect2
- MEOX1 | c.-216T>C | 5'UTR (SNP) | VAF 7/116 reads (6%) | called by muse, mutect2
- MIR5195 | chr14:106851229 A>T | 5'Flank (SNP) | VAF 89/237 reads (38%) | catalogued as rs578215375; called by muse, mutect2, varscan2
- MIR5195 | chr14:106851342 C>T | 5'Flank (SNP) | VAF 63/152 reads (41%) | catalogued as rs544762978; called by muse, mutect2, varscan2
- MSR1 | c.1034-464del | Intron (DEL) | VAF 30/108 reads (28%) | called by mutect2, pindel, varscan2
- MTAP | c.813+4271A>T | Intron (SNP) | VAF 15/41 reads (37%) | called by muse, mutect2, varscan2
- NDUFB4 | c.328-18T>G | Intron (SNP) | VAF 11/37 reads (30%) | called by muse, mutect2, varscan2
- NKX6-3 | c.*398G>A | 3'UTR (SNP) | VAF 35/137 reads (26%) | called by muse, mutect2, varscan2
- NPSR1 | c.280+1262T>A | Intron (SNP) | VAF 27/80 reads (34%) | called by muse, mutect2
- NR2F1 | c.*87G>C | 3'UTR (SNP) | VAF 24/62 reads (39%) | called by muse, varscan2
- PPP2R2D | c.*3530G>A | 3'UTR (SNP) | VAF 40/194 reads (21%) | called by muse, mutect2, varscan2
- PRDM2 | c.*933C>T | 3'UTR (SNP) | VAF 45/121 reads (37%) | catalogued as rs571930943, COSV99340723; called by muse, mutect2, varscan2
- RASGRF1 | c.*794A>C | 3'UTR (SNP) | VAF 67/248 reads (27%) | called by muse, mutect2, varscan2
- RN7SL484P | chr15:99792642 G>A | 3'Flank (SNP) | VAF 13/171 reads (8%) | catalogued as rs187309064; called by muse, mutect2
- RNASE9 | c.-14-1543G>A | Intron (SNP) | VAF 91/266 reads (34%) | catalogued as rs924682856, COSV100141412; called by muse, mutect2, varscan2
- RNF26 | c.*545G>A | 3'UTR (SNP) | VAF 24/99 reads (24%) | catalogued as rs950144765; called by muse, mutect2, varscan2
- RSF1 | c.*938T>A | 3'UTR (SNP) | VAF 14/57 reads (25%) | called by muse, mutect2, varscan2
- SLC22A18 | c.-4C>A | 5'UTR (SNP) | VAF 24/56 reads (43%) | catalogued as COSV100388638; called by muse, mutect2
- SNPH | c.*1373C>T | 3'UTR (SNP) | VAF 10/142 reads (7%) | called by muse, mutect2
- SYT11 | c.*1344C>T | 3'UTR (SNP) | VAF 19/111 reads (17%) | called by muse, mutect2, varscan2
- TM6SF1 | chr15:83107584 C>T | 5'Flank (SNP) | VAF 6/29 reads (21%) | catalogued as rs972257033; called by muse, mutect2, varscan2
- TRPV3 | c.*1518C>T | 3'UTR (SNP) | VAF 23/76 reads (30%) | catalogued as rs1278351668; called by muse, mutect2, varscan2
- VGLL3 | c.*5563T>A | 3'UTR (SNP) | VAF 12/38 reads (32%) | catalogued as rs556892409, COSV101264179; called by muse, mutect2, varscan2
- VIM | c.625-30C>A | Intron (SNP) | VAF 4/29 reads (14%) | called by muse, mutect2, varscan2
- WDR86 | c.-211C>T | 5'UTR (SNP) | VAF 12/101 reads (12%) | called by muse, mutect2, varscan2
- ZNF641 | c.*2577G>A | 3'UTR (SNP) | VAF 24/63 reads (38%) | called by muse, mutect2, varscan2
